Gene-level copy-number profile of tumor specimen TCGA-3A-A9IS-01A from TCGA case TCGA-3A-A9IS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 67.4 years (24,621 days).
Specimen TCGA-3A-A9IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.948ab0e6-67ab-4abb-8a00-672050aeda9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9IS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/59e7900a-f08e-4701-9f16-2f9e1007139d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,453; copy number 2: 24,448; copy number 3: 12,274; copy number 4: 8,780; copy number 5: 9,179; copy number 6: 2,421; copy number 7: 217; copy number 8: 13; copy number 11: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9IS-01A-21D-A396-01): tumor purity 0.99, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,843 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,241,916–7,790,482, 3 genes, copy number 5: AC066585.1, GRM7-AS1, AC077690.1.
- chr3:34,203,244–36,170,448, 11 genes, copy number 5: AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1.
- chr4:49,096–29,907,791, 500 genes, copy number 5–11 (broad region; genes not listed).
- chr4:32,583,855–37,449,463, 30 genes, copy number 5–6 (within-gene range 4–6): AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2.
- chr4:42,706,107–59,630,324, 227 genes, copy number 5–7 (broad region; genes not listed).
- chr4:60,750,575–126,017,357, 906 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr4:126,431,694–160,818,869, 469 genes, copy number 5–8 (broad region; genes not listed).
- chr4:161,383,897–171,059,163, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:4,451,930–5,140,119, 13 genes, copy number 5: AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2.
- chr5:8,614,356–19,234,487, 180 genes, copy number 5 (broad region; genes not listed).
- chr5:21,341,833–21,779,522, 5 genes, copy number 5 (within-gene range 4–5): GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–22,152,356, 3 genes, copy number 5: HSPD1P1, AC139497.1, PMCHL1.
- chr5:27,217,714–82,977,153, 849 genes, copy number 5–6 (broad region; genes not listed).
- chr5:83,746,388–129,461,076, 552 genes, copy number 5–8 (broad region; genes not listed).
- chr5:131,797,415–156,963,226, 631 genes, copy number 5–8 (broad region; genes not listed).
- chr5:158,078,099–181,342,213, 461 genes, copy number 5–6 (broad region; genes not listed).
- chr7:126,980,967–127,485,804, 9 genes, copy number 5: AC000362.1, MIR592, GRM8-AS1, PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1.
- chr7:136,485,656–137,847,092, 14 genes, copy number 5: ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1, DGKI, AC090498.1, AC009245.1.
- chr8:5,659,679–12,818,291, 287 genes, copy number 5 (broad region; genes not listed).
- chr8:16,107,878–39,284,917, 450 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:40,530,590–49,229,174, 147 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:52,110,839–119,673,453, 980 genes, copy number 5–7 (broad region; genes not listed).
- chr8:120,761,253–145,066,685, 451 genes, copy number 5–8 (within-gene range 5–16) (broad region; genes not listed).
- chr9:19,460,926–19,786,928, 3 genes, copy number 7 (within-gene range 4–7): MAP1LC3BP1, SLC24A2, C11orf98P1.
- chr9:82,543,718–82,744,792, 3 genes, copy number 6: AL356490.1, AL353774.1, RPS6P12.
- chr9:100,731,240–101,793,756, 22 genes, copy number 5: ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4.
- chr9:115,119,539–118,083,382, 28 genes, copy number 5: AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9.
- chr9:119,495,375–119,937,832, 2 genes, copy number 5 (within-gene range 4–5): AC006288.1, LINC01613.
- chr12:66,767–32,756,463, 827 genes, copy number 5 (broad region; genes not listed).
- chr12:32,985,838–94,307,675, 1,254 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:97,150,081–101,210,238, 66 genes, copy number 6 (broad region; genes not listed).
- chr12:101,280,105–133,214,832, 834 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr14:78,059,942–78,060,278, 1 gene, copy number 5: FXNP1.
- chr14:78,177,803–78,709,934, 5 genes, copy number 5: RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3.
- chr18:45,423,764–45,611,540, 6 genes, copy number 5: SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1.
- chr18:52,283,909–52,339,025, 2 genes, copy number 5: AC016383.2, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes, copy number 5: AC011155.1, VN1R76P.
- chr19:24,004,358–28,125,430, 22 genes, copy number 5–6: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–7 (broad region; genes not listed).
- chr22:26,161,834–26,169,341, 2 genes, copy number 6: LINC02559, AL022337.1.

Autosomal genes at a single copy (total copy number 1): 83. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
